Surgical pathology report (de-identified scan), TCGA case TCGA-FT-A61P, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University of Miami, specimen TCGA-FT-A61P-01A (Primary Tumor).

[page 1 of 4]
ICD-O-3
Carcinoma, urothelial 8120/3
Site Bladder, lateral posterior wall
C67.9
Bladder wall NOS
C67.9
JW 5/10/13

*** FINAL REPORT ***
SURGICAL PATHOLOGY REPORT

AGE/SEX: /M

RECEIVED:

COLLECTED:

SPECIMEN ID:

A. URETER - LEFT DISTAL URETER FS, B. URETER - RT DISTAL URETER FS,
C. URETHRA - MEMBRANE OF THE URETHRA,
D. LYMPH NODE - EXTERNAL ILIAC LYMPH NODE LEFT SIDE #1,
E. LYMPH NODE - INTERNAL ILIAC LYMPH NODE LEFT SIDE,
F. LYMPH NODE - COMMON ILIAC LYMPH NODE LEFT SIDE,
G. LYMPH NODE - EXTERNAL ILIAC LYMPH NODE LEFT SIDE #2,
H. LYMPH NODE - LEFT OBTURATOR LYMPH NODE,
I. LYMPH NODE - RIGHT EXTERNAL ILIAC LYMPH NODE, J. PROSTATE - BLADDER AND
PROSTATE,
K. LYMPH NODE - OBTURATOR LYMPH NODE RIGHT SIDE,
L. LYMPH NODE - INTERNAL ILIAC LYMPH NODE

A. LEFT DISTAL URETER:

Segment of ureter, negative for carcinoma in situ; negative for invasive carcinoma.

B. RIGHT DISTAL URETER:

Segment of ureter, negative for carcinoma in situ; negative for invasive carcinoma.

C. MEMBRANE OF THE URETHRA:

Urethral mucosa with focal chronic inflammation, negative for carcinoma.

D. EXTERNAL ILIAC LYMPH NODE LEFT SIDE #1"

Four lymph nodes, negative for carcinoma (0/4).

E. INTERNAL ILIAC LYMPH NODE LEFT SIDE:

Two lymph nodes, negative for carcinoma (0/2).

F. COMMON ILIAC LYMPH NODE LEFT SIDE:

One lymph node, negative for carcinoma (0/1).

G. EXTERNAL ILIAC LYMPH NODE LEFT SIDE #2:

METASTATIC CARCINOMA to one lymph node, (1/1).

Tumor deposit measures 1.2 cm in greatest dimension.

Negative for extranodal extension.

H. LEFT OBTURATOR LYMPH NODE:

METASTATIC CARCINOMA to one of three lymph nodes (1/3).

Tumor deposit measures 1.4 cm in greatest dimension.

Negative for extranodal extension.

I. RIGHT EXTERNAL ILIAC LYMPH NODE:

[page 2 of 4]
One lymph node, negative for carcinoma (0/1).

J. BLADDER AND PROSTATE, RADICAL CYSTOPROSTATECTOMY:

URINARY BLADDER:

INVASIVE HIGH GRADE UROTHELIAL CARCINOMA, 3.0 cm in greatest dimension.
Tumor invades through the muscularis propria into perivesical adipose tissue.
Surgical resection margins, negative for tumor.

PROSTATE:

Benign prostatic tissue.
AJCC classification (7th edition): pT3b, pN2, pMn/a
See Surgical Pathology Cancer Case Summary

K. OBTURATOR LYMPH NODE RIGHT SIDE:

One lymph node, negative for carcinoma (0/1).

L. INTERNAL ILIAC LYMPH NODE:

One lymph node, negative for carcinoma (0/1).

Surgical Pathology Cancer Case Summary:

Specimen Type: Bladder and prostate

Procedure: Radical cystoprostatectomy

Tumor Site: Left lateral wall

Posterior wall

Tumor Size: Greatest dimension: 3.0 cm

Histologic Type: Urothelial carcinoma

Histologic Grade (WHO 2004/ISUP; WHO 1973) :

High-Grade (WHO 2004/ISUP; WHO 1973 grade 3 of 3)

Microscopic Tumor Extension: Perivesical fat

Margins: Margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 0.9 cm

Specify margin: Deep margin

Lymph-Vascular Invasive: Not identified

Pathologic Staging (pTNM):

Primary Tumor (pT): pT3b: Tumor invades perivesical tissue

Regional Lymph Nodes (pN): pN2 Multiple regional lymph node metastasis in the true pelvis
(hypogastric, obturator, external iliac or presacral lymph node metastasis)

Number examined; 14

Number involved: 2

Distant Metastasis (pM): Not applicable

Dictated by: XXX

CLINICAL HISTORY

PRE-OP DX: Not provided

PROCEDURE: Radical cystectomy

RELEVANT CLINICAL HX: Bladder cancer

GROSS DESCRIPTION:

[page 3 of 4]
A. Received fresh and labeled "Left distal ureter" is a fragment of ureter with lumen that measures 0.3 x 0.3 x 0.2 cm. Submitted in toto for frozen section.

B. Received fresh and labeled "Right distal ureter" is a fragment of ureter with lumen that measures 0.3 x 0.3 x 0.2 cm. Submitted in toto for frozen section.

C. Received in formalin and labeled "Membrane of the urethra" is a fragment of gray/tan tissue that measures 1.6 x 0.9 x 0.8 cm and it is friable. Submitted in toto in two cassettes.

D. Received in formalin and labeled "External iliac lymph node left side #1" is a fragment of fibroadipose tissue that measures 4.4 x 3.5 x 0.6 cm. Five possible lymph nodes were identified. The largest one measures 1.7 cm in greatest dimension. Sections submitted as follows:

1 One lymph node bisected submitted in toto

2 One lymph node in toto

3 Three lymph nodes in toto

E. Received in formalin and labeled "Internal iliac lymph node left side" is a fragment of fibroadipose tissue that measures 3.4 x 2.5 x 0.5 cm. No lymph nodes are grossly identified. Specimen submitted in three cassettes.

F. Received in formalin and labeled "Common iliac lymph node left side" are three fragments of fibroadipose tissue that measures in aggregate 2.7 x 2.0 x 0.7 cm. Two possible lymph nodes were grossly identified. The largest one measures 1.4 cm in greatest dimension. Sections submitted as follows:

1 One possible lymph node

2 One possible lymph node

G. Received in formalin and labeled "External iliac lymph node left side #2" is a fragment of fibroadipose tissue that measures 3.1 x 1.4 x 1.0 cm. One lymph node was grossly identified measuring 1.9 x 1.3 x 1.0 cm. Submitted in toto in two cassettes.

H. Received in formalin and labeled "Left obturator lymph node" are multiple fragments of fibroadipose tissue that measures in aggregate 6.2 x 2.5 x 1.2 cm. Three possible lymph nodes are grossly identified. The largest one measures 3.0 cm in greatest dimension. Sections submitted as follows:

1-4 Representative sections of largest lymph node

5 One lymph node bisected in toto

6 One lymph node bisected in toto

I. Received in formalin and labeled "Right external iliac lymph node" is a fragment of fibroadipose tissue that measures 3.6 x 2.0 x 1.5 cm. One possible lymph node is identified measuring 2.4 cm in greatest dimension. Sections submitted as follows:

1&2 One lymph node bisected in toto

J. Received in formalin and labeled "Bladder and prostate" is a radical cystoprostatectomy specimen containing bladder (10.0 x 8.5 x 4.0 cm), prostate (5.5 x 4.0 x 3.0 cm), right ureter (0.2 cm in length x 0.2 cm in diameter) and left ureter (0.2 cm in length x 0.2 cm in diameter). The outer surface of the bladder is smooth with yellow and perivesicle soft tissue attached and it is inked in black. The bladder is opened anteriorly through the urethra and the incision is extended to the dome. A (3.0 x 2.5 x 1.0 cm) tan pink mass is located in the posterior left lateral wall of

[page 4 of 4]
the bladder. The mass is ulcerated and firm. The mass is extending into the perivesicle soft tissue and is at 0.2 cm away from the deep margin (inked black). The mass is 1.0 cm away from the left ureteral orifice and 3.0 cm away from the right ureteral orifice. The prostate is inked on its outer surface and serially sectioned through the posterior surface perpendicular to prostatic urethra. The parenchyma is white and yellow, no lesion is grossly identified. The right side of the prostate is inked in green and the left side is inked in black. The right seminal vesicle measures 2.7 x 1.5 x 1.0 cm and the left seminal vesicle measures 3.0 x 1.5 x 1.0 cm. The right vas deferens measures 10.5 x 0.2cm and the left vas deferens measures 8.5 x 0.2 cm. Perivesical soft tissue is thinly sectioned and no lymph nodes are identified.

Sections submitted as follows:

- Cassette#1: Left urethral orifice in relation to tumor
- Cassette#2: Right urethral orifice in relation to bladder
- Cassette#3-4: Deepest extent of tumor invasion including deep margin
- Cassette#5-6: Additional sections of tumor with deep margin
- Cassette#7-8: Tumor with adjacent bladder mucosa
- Cassette#9: Right lateral bladder wall
- Cassette#10: Left ureter
- Cassette#11: Right ureter
- Cassette#12: Anterior bladder wall
- Cassette#13: Right apex
- Cassette#14: Left apex
- Cassette#15: Right prostate
- Cassette#16: Left prostate
- Cassette#17: Right prostate with seminal vesicle
- Cassette#18-20: Left prostate with seminal vesicle and bladder mucosa
- Cassette#21: Left seminal vesicle
- Cassette#22: Right seminal vesicle

K. Received in formalin and labeled "Obturator lymph node right side" is a fragment of fibroadipose tissue that measures 7.1 x 3.0 x 1.2 cm. One possible lymph node was grossly identified that measures 4.0 cm in greatest dimension. Sections submitted as follows:

- 1&2 One lymph node bisected submitted in toto

L. Received in formalin and labeled "Internal iliac lymph node" is a fragment of fibroadipose tissue that measures 3.9 x 3.0 x 1.5 cm. Three possible lymph nodes are identified. The largest one measures 1.5 cm in greatest dimension. Sections submitted as follows:

- 1 One lymph node bisected submitted in toto
- 2 Two lymph nodes submitted in toto

OPERATING ROOM CONSULT

AFS. LEFT DISTAL URETER:

Negative for carcinoma and/or dysplasia.

BFS. RIGHT DISTAL URETER:

Negative for carcinoma and/or dysplasia.

Source: NCI Genomic Data Commons file dc38cd65-78d6-44b2-8715-50d64d25a10b (TCGA-FT-A61P.F2B10F1A-5A97-4FAE-8DF5-153FFBDE2C35.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).